Somatic mutation profile of tumor specimen TCGA-61-1903-01A (aliquot TCGA-61-1903-01A-01W-0639-09) from TCGA case TCGA-61-1903, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 55.8 years (20,381 days).
Specimen TCGA-61-1903-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f74c450-09af-4db5-b3b9-fbbd503cf669.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-1903-11A (Solid Tissue Normal), aliquot TCGA-61-1903-11A-01W-0640-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2779a17f-574a-4ab9-aad9-4b2c6866499a

The open-access MAF lists 55 somatic variants for this specimen: 47 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Nonsense Mutation 6, Silent 4, Splice Site 4, Frame Shift Del 2, 5'Flank 2, Intron 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 20/30 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS4 | c.1046A>T p.E349V | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63488556; called by muse, varscan2
- AGXT2 | c.602G>C p.S201T | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.078); catalogued as COSV51489964; called by muse, mutect2, varscan2
- AKAP13 | c.7099C>T p.Q2367* (on ENST00000394518 / NM_007200.5; = p.Q2371* on NM_006738.6) | Nonsense Mutation (SNP) | VAF 205/736 reads (28%) | catalogued as COSV63467509; called by muse, mutect2, varscan2
- ANKRD26 | c.2443C>G p.Q815E | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as COSV101063421; called by muse, mutect2, varscan2
- ANKS1B | c.257A>G p.N86S | Missense Mutation (SNP) | VAF 89/109 reads (82%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100247950; called by muse, mutect2, varscan2
- APBA2 | c.2197C>T p.P733S | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99721227; called by muse, mutect2, varscan2
- BRCA2 | c.5729A>G p.N1910S | Missense Mutation (SNP) | VAF 64/82 reads (78%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs276174863, COSV66461231; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- BZW2 | c.1106A>T p.K369I | Missense Mutation (SNP) | VAF 106/256 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51754556, COSV51757235; called by muse, mutect2, varscan2
- C19orf12 | c.151T>A p.F51I (on ENST00000392278 / NM_001031726.3; = p.F40I on NM_031448.6) | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.891); catalogued as COSV100080649; called by muse, mutect2, varscan2
- C1orf74 | c.349G>T p.V117F | Missense Mutation (SNP) | VAF 85/216 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs868287276, COSV50559028; called by muse, mutect2, varscan2
- CACNA1C | c.1489A>T p.I497F | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as COSV100222230; called by muse, mutect2, varscan2
- CACNA1E | c.5147A>G p.N1716S | Missense Mutation (SNP) | VAF 233/468 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62414733; called by muse, mutect2, varscan2
- CALN1 | c.278A>G p.D93G (on ENST00000329008 / NM_001017440.3; = p.D135G on NM_031468.4) | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV100209461, COSV61148062; called by muse, varscan2
- CKAP2L | c.699T>G p.N233K | Missense Mutation (SNP) | VAF 72/182 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV56697966; called by muse, mutect2, varscan2
- CPS1 | c.381+1G>A p.X127_splice | Splice Site (SNP) | VAF 111/303 reads (37%) | catalogued as COSV51822143; called by muse, mutect2, varscan2
- DLG2 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 175/433 reads (40%) | catalogued as COSV101074484, COSV65860536; called by muse, mutect2, varscan2
- DMD | c.4556T>G p.V1519G | Missense Mutation (SNP) | VAF 82/107 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100822801; called by muse, mutect2
- FARS2 | c.1304A>T p.Q435L | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV51174185; called by muse, mutect2, varscan2
- FLNC | c.7123G>A p.V2375I | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.529); catalogued as rs768941858, COSV57962607; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GDF3 | c.716A>G p.N239S | Missense Mutation (SNP) | VAF 114/232 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as rs764408748, COSV61713448; called by muse, mutect2, varscan2
- GIPR | c.925-1G>C p.X309_splice | Splice Site (SNP) | VAF 52/112 reads (46%) | catalogued as COSV54426020; called by muse, mutect2, varscan2
- GPRC5B | c.597C>A p.D199E | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56028424; called by muse, varscan2
- GSC | c.759G>C p.L253F | Missense Mutation (SNP) | VAF 61/108 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.095); catalogued as COSV53077064, COSV53077706; called by muse, mutect2, varscan2
- LRRK1 | c.3869G>C p.R1290T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.185); catalogued as COSV99443166; called by muse, mutect2, varscan2
- LY75 | c.326A>C p.K109T | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV55112057; called by muse, mutect2, varscan2
- MAGI2 | c.3256C>G p.P1086A | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV62692064; called by muse, mutect2, varscan2
- MMP12 | c.938G>C p.R313T | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV100405078, COSV58260685; called by muse, mutect2, varscan2
- MTMR12 | c.1086G>A p.W362* | Nonsense Mutation (SNP) | VAF 67/116 reads (58%) | catalogued as COSV53787358; called by muse, mutect2, varscan2
- NCOA3 | c.2699C>G p.S900* | Nonsense Mutation (SNP) | VAF 82/255 reads (32%) | catalogued as COSV59068040; called by muse, mutect2, varscan2
- OR5AP2 | c.920T>A p.L307Q | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as COSV57258617; called by muse, mutect2, varscan2
- OR7G2 | c.20T>G p.L7R | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); catalogued as COSV59688814; called by muse, mutect2, varscan2
- PEG3 | c.4643G>A p.R1548H | Missense Mutation (SNP) | VAF 134/297 reads (45%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs773370734, COSV55626889; called by muse, mutect2, varscan2
- PTPN21 | c.588-2A>G p.X196_splice | Splice Site (SNP) | VAF 146/486 reads (30%) | catalogued as COSV60851414; called by muse, mutect2, varscan2
- PTPN22 | c.1163del p.D388Afs*8 (on ENST00000359785 / NM_001193431.2; = p.D333Afs*8 on NM_012411.5) | Frame Shift Del (DEL) | VAF 91/260 reads (35%) | catalogued as COSV63086321; called by mutect2, pindel, varscan2
- RBM42 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs1373786771, COSV52898707; called by muse, mutect2, varscan2
- SH3TC2 | c.3192G>T p.E1064D | Missense Mutation (SNP) | VAF 54/95 reads (57%) | SIFT tolerated (0.53); PolyPhen benign (0.174); catalogued as COSV60467200; called by muse, mutect2, varscan2
- SYVN1 | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 26/70 reads (37%) | catalogued as COSV53697016; called by muse, mutect2, varscan2
- TGM4 | c.787G>C p.V263L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56096042, COSV99942348; called by muse, mutect2, varscan2
- THOC5 | c.1607C>G p.T536S | Missense Mutation (SNP) | VAF 90/198 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.078); catalogued as COSV63800741; called by muse, varscan2
- TMEM260 | c.875T>C p.M292T | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.346); catalogued as rs751461288, COSV55102047; called by muse, mutect2, varscan2
- XIRP2 | c.974G>A p.R325H (on ENST00000628543; = p.R500H on NM_152381.6) | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201393718, COSV54690793, COSV54711854; called by muse, mutect2, varscan2
- ZNF559 | c.214C>G p.Q72E | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.044); catalogued as COSV57837061; called by muse, mutect2, varscan2
- CDC14A | c.1436_1454del p.S479* | Frame Shift Del (DEL) | VAF 77/265 reads (29%) | called by mutect2, pindel, varscan2
- NBPF20 | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 174/811 reads (21%) | called by muse, mutect2, varscan2
- PGAM2 | c.14_31del p.R5_R10del | In Frame Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, varscan2
- SNRNP200 | c.1102_1119+1del p.X368_splice | Splice Site (DEL) | VAF 208/754 reads (28%) | called by mutect2, pindel, varscan2
- LRRC41 | c.1600C>T p.L534= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as COSV100586553; called by muse, mutect2, varscan2
- OR2T2 | c.174A>C p.T58= | Silent (SNP) | VAF 92/648 reads (14%) | catalogued as COSV61618859; called by muse, mutect2, varscan2
- SCAF8 | c.2808G>T p.G936= | Silent (SNP) | VAF 228/301 reads (76%) | catalogued as COSV65793536; called by muse, varscan2
- ZNF229 | c.1365C>T p.H455= | Silent (SNP) | VAF 76/169 reads (45%) | catalogued as rs1568401752, COSV52164391; called by muse, mutect2, varscan2
- FBXW7 | c.502-2550T>G | Intron (SNP) | VAF 63/83 reads (76%) | catalogued as rs1258384405, COSV55948833; called by muse, mutect2, varscan2
- PNO1 | chr2:68157607 T>C | 5'Flank (SNP) | VAF 29/53 reads (55%) | called by muse, mutect2, varscan2
- PNO1 | chr2:68157608 G>T | 5'Flank (SNP) | VAF 30/54 reads (56%) | called by muse, mutect2, varscan2
- SNORD115-6 | n.62A>T | RNA (SNP) | VAF 35/109 reads (32%) | catalogued as rs1256507321; called by muse, mutect2, varscan2
